Gene-level copy-number profile of tumor specimen TCGA-CZ-5464-01A from TCGA case TCGA-CZ-5464, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 69.7 years (25,463 days).
Specimen TCGA-CZ-5464-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.4dbc7fe6-5878-429c-9c0c-3ee92fe0d981.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CZ-5464-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b70258a7-4124-45c0-a8f1-c4e9f88beb6e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 1,341; copy number 4: 38,892; copy number 6: 18,314; copy number 8: 29; copy number 10: 1,244.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CZ-5464-01A-01D-1499-01): tumor purity 0.48, ploidy 2.37, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,244 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:121,040,090–124,438,625, 41 genes, copy number 10 (within-gene range 6–10): AC008565.1, AC113352.1, AC008568.1, AC010350.1, AC008568.2, RPL23AP44, AC106806.1, AC106806.2, FTMT, SRFBP1, LOX, AC010255.1, ZNF474, AC010255.2, ZNF474-AS1, AC113349.2, SNCAIP, AC113349.1, AC119150.1, AC119150.2, MGC32805, LINC02201, ARGFXP1, SNX2, AC008669.1, SNX24, RN7SL689P, PPIC, PPIC-AS1, RN7SL711P, AC106786.1, PRDM6, AC010493.1, CEP120, KRT8P33, HMGB3P17, AC026422.1, CSNK1G3, KRT18P16, LINC01170, HMGB1P29.
- chr5:124,808,981–125,602,227, 1 gene, copy number 10 (within-gene range 6–10): LINC02240.
- chr5:124,993,408–181,342,213, 1,202 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
